Surgical pathology report (de-identified scan), TCGA case TCGA-TQ-A8XE, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site University of Sao Paulo, specimen TCGA-TQ-A8XE-02A (Recurrent Tumor).

ICD-O-3

Oligodendroglioma, grade III
9451/3

Site ^{CSCF}
Supratentorial brain NOS
path ^{C71.0}
Brain NOS C71.9

Nature of material: Brain

Biopsy number:

ANATOMOPATHOLOGIC RESULT

9/1/29/14

MACROSCOPY

Received several fragments of light-brown tissue with dark-brown spots and firm consistency, measuring together 5.5 x 2.5 x 1.3 cm.

MICROSCOPY

The histological sections evidence malignancy with moderate to high cellularity, composed of pleomorphic cells with eosinophilic and large cytoplasm, some multinucleated, with enlarged nuclei, vesicular aspect and prominent nucleoli. Presence of sparse mitosis. There are frequent cells with minigemistocystic standard. Shows foci of necrosis and microvascular proliferation.

IMMUNOHISTOCHEMISTRY EVIDENCE:

-Cell proliferation Index (ki67): positive in 8% of neoplastic cells.

DIAGNOSTIC

Resection product of brain tumor:

-Anaplastic oligodendroglioma (GRADE III - WHO).

PARTICIPANTS OF APPRAISAL REPORT

- ISSUER
- PATHOLOGY ASSISTANT

Recurrent for primary
oligodendroglioma, grade III. BCC

Dual/Syncronous Primary	☒	

Source: NCI Genomic Data Commons file 3b928256-9ba2-4135-b1f8-135ae9f60038 (TCGA-TQ-A8XE.845B196D-DB8C-4AA6-A506-ED4D4364B51B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).